Somatic mutation profile of tumor specimen TARGET-30-PATYPH-01A (aliquot TARGET-30-PATYPH-01A-01D) from TARGET case TARGET-30-PATYPH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.4 years (2,701 days).
Specimen TARGET-30-PATYPH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a920316-bdc7-4ba3-8d3c-6962c9907c28.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYPH-10A (Blood Derived Normal), aliquot TARGET-30-PATYPH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8294766a-c3f8-4c47-bc33-97798976f182

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 59/136 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 35/40 reads (88%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL5A3 | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53421726; called by muse, mutect2, varscan2
- ATRX | c.3644_3667del p.S1215_E1223delins* | Nonsense Mutation (DEL) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
- CBFA2T2 | c.*164G>A | 3'UTR (SNP) | VAF 56/131 reads (43%) | catalogued as COSV60802556; called by muse, mutect2, varscan2
- CTNNB1 | c.*749G>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
